Somatic mutation profile of tumor specimen TCGA-14-3476-01B (aliquot TCGA-14-3476-01B-01D-1353-08) from TCGA case TCGA-14-3476, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.4 years (27,172 days).
Specimen TCGA-14-3476-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c99527e-ebfc-4626-9ffa-633fa4196dbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-3476-10A (Blood Derived Normal), aliquot TCGA-14-3476-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c54653d-200f-43c1-bdf9-44cdc687ab57

The open-access MAF lists 64 somatic variants for this specimen: 43 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, RNA 3, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 14/439 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2
- ATP2A1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303823906, COSV62870655; called by muse, mutect2, varscan2
- BOD1L1 | c.8557G>A p.E2853K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.417); catalogued as COSV50043969; called by muse, mutect2, varscan2
- C3orf20 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs151210868; called by muse, mutect2, varscan2
- CCDC8 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as rs1366022869, COSV56774443; called by muse, mutect2, varscan2
- CEACAM7 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50074255, COSV50075512; called by muse, mutect2, varscan2
- COL6A6 | c.4682G>A p.G1561D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62034334; called by muse, mutect2, varscan2
- CPS1 | c.3464C>T p.A1155V | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766125631, CM114377, CM114378, COSV51821318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHRS7C | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs765311049, COSV57652092; called by muse, mutect2, varscan2
- DNAH11 | c.4126G>A p.V1376I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs531283952, COSV60938522, COSV60977719; called by muse, mutect2, varscan2
- DSTYK | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769627475, COSV65688086; called by muse, mutect2
- EHD3 | c.1056C>A p.D352E | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV59032517; called by muse, mutect2
- GABRB3 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54679171; called by muse, mutect2, varscan2
- GIMAP8 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV56232454, COSV56233203; called by muse, mutect2, varscan2
- GRM3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as COSV64467861; called by muse, mutect2
- HAVCR1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV59402848; called by muse, mutect2, varscan2
- HSPG2 | c.11513C>T p.T3838M | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs750376699, COSV65934259; called by muse, mutect2, varscan2
- HSPH1 | c.2086A>T p.M696L | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs548315411, COSV60713143; called by muse, mutect2, varscan2
- IKZF3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs1171389897, COSV53105779; called by muse, mutect2, varscan2
- IMPG1 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV64060851; called by muse, mutect2, varscan2
- KCNQ4 | c.1292+1G>T p.X431_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV61275134; called by muse, mutect2, varscan2
- KIR3DL2 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54394643; called by muse, varscan2
- MARCO | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59057104, COSV59057381; called by muse, mutect2, varscan2
- MUC3A | c.8567C>T p.P2856L | Missense Mutation (SNP) | VAF 80/535 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as rs1241436237, COSV100114915; called by muse, mutect2, varscan2
- MYBPC3 | c.3415G>A p.V1139I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs373519667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCOR2 | c.1021del p.R341Afs*54 | Frame Shift Del (DEL) | VAF 55/218 reads (25%) | catalogued as COSV62301510; called by mutect2, pindel, varscan2
- NDUFAF2 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56942961; called by muse, mutect2, varscan2
- OR4A47 | c.675C>A p.N225K | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as rs774349068, COSV71445102; called by muse, mutect2, varscan2
- OR52A1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs371802271; called by muse, mutect2, varscan2
- OR8I2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs749476782, COSV56166494, COSV56170718; called by muse, mutect2, varscan2
- PCDHGA12 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52764021; called by muse, mutect2
- PRB1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 280/1065 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV53702660, COSV53706049; called by muse, mutect2, varscan2
- PTDSS1 | c.283C>G p.R95G | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61266093; called by muse, mutect2, varscan2
- SGO2 | c.2712T>G p.N904K | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); catalogued as COSV63417264; called by muse, mutect2, varscan2
- SLC6A6 | c.1154C>G p.T385R | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV62652089; called by muse, mutect2, varscan2
- SP5 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64623678; called by muse, mutect2
- TCTN2 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs1424979579, COSV57634374; called by muse, mutect2, varscan2
- TTC21A | c.631G>C p.G211R | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100087840, COSV57188624; called by muse, mutect2
- UACA | c.4022T>A p.L1341H | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59858663; called by muse, mutect2, varscan2
- USH2A | c.7061G>A p.R2354H | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs201386640, CM065510, COSV56331304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAMP7 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV52902684; called by muse, mutect2, varscan2
- WDR45 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs887699606, COSV59876764; called by muse, mutect2, varscan2
- ZNF770 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV62544823; called by muse, mutect2, varscan2
- ACOX2 | c.60C>T p.P20= | Silent (SNP) | VAF 215/681 reads (32%) | catalogued as rs762633744, COSV57147685; called by muse, mutect2, varscan2
- ATP2B1 | c.849A>G p.Q283= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV53811778; called by muse, mutect2, varscan2
- BTBD9 | c.1320C>A p.V440= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV58421677, COSV58433936; called by muse, mutect2
- CALN1 | c.447G>A p.T149= (on ENST00000329008 / NM_001017440.3; = p.T191= on NM_031468.4) | Silent (SNP) | VAF 81/304 reads (27%) | catalogued as rs766714139, COSV61119273; called by muse, mutect2, varscan2
- CLEC1A | c.237C>A p.S79= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV59533649; called by muse, mutect2, varscan2
- EGF | c.2922T>C p.S974= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV54483226; called by muse, mutect2
- GIMAP1 | c.852C>T p.G284= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs770099581, COSV56187177, COSV56187663; called by muse, mutect2, varscan2
- HELZ2 | c.2106G>T p.R702= (on ENST00000467148 / NM_001037335.2; = p.R133= on NM_033405.3) | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100915639; called by muse, mutect2
- IL22RA2 | c.27C>T p.G9= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs770829398, COSV51664395, COSV51665099; called by muse, mutect2, varscan2
- LRP1B | c.10482G>T p.R3494= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as COSV67261351, COSV67263814; called by muse, mutect2
- MAP2K3 | c.555G>A p.S185= (on ENST00000342679 / NM_145109.3; = p.S156= on NM_002756.4) | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs752706180, COSV57575656; called by muse, varscan2
- MUC16 | c.7072C>A p.R2358= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV67485774; called by muse, mutect2, varscan2
- MUC5B | c.12798G>A p.T4266= | Silent (SNP) | VAF 20/173 reads (12%) | catalogued as rs756307198, COSV71591930; called by muse, mutect2, varscan2
- NLRP7 | c.447C>T p.D149= | Silent (SNP) | VAF 27/909 reads (3%) | catalogued as rs1221420376, COSV60179966; called by muse, mutect2
- OPN1LW | c.171T>C p.S57= | Silent (SNP) | VAF 76/128 reads (59%) | catalogued as COSV64065134; called by muse, mutect2, varscan2
- PCDHA5 | c.1629T>A p.P543= | Silent (SNP) | VAF 48/186 reads (26%) | catalogued as rs1554129330, COSV65356290; called by muse, mutect2, varscan2
- SMARCA4 | c.3144C>T p.H1048= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs778369345, COSV60805326; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC073310.1 | n.562G>A | RNA (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.87C>A | RNA (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- SNORD115-7 | n.72C>T | RNA (SNP) | VAF 87/360 reads (24%) | catalogued as rs771396117; called by muse, mutect2, varscan2
- TTN | c.10360+3931G>T | Intron (SNP) | VAF 31/117 reads (26%) | catalogued as COSV60273837; called by muse, mutect2, varscan2
